Gene-level copy-number profile of specimen HCM-CSHL-0073-C25-85B from HCMI case HCM-CSHL-0073-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 55.3 years (20,210 days).
Specimen HCM-CSHL-0073-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7772a2d3-ec61-4989-9c5b-6143b76e80f8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0073-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/679b62ff-db17-4d9e-8f20-453c296f26d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 11,394; copy number 2: 45,473; copy number 3: 951; copy number 4: 1,084.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,523,648–49,557,400, 5 genes: AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 8,538. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
